Gene-level copy-number profile of tumor specimen TCGA-ZJ-AAXN-01A from TCGA case TCGA-ZJ-AAXN, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Age at diagnosis: 34.8 years (12,701 days).
Specimen TCGA-ZJ-AAXN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.7234083d-3fc8-4781-9693-d607db2219d5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZJ-AAXN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c18f83e2-e10a-4fbc-9e75-87694f0fcdac

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 4,467; copy number 2: 49,703; copy number 3: 4,670; copy number 4: 421; copy number 6: 524; copy number 20: 3; copy number 30: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZJ-AAXN-01A-11D-A42N-01): tumor purity 0.79, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,167,357, 1 gene: RNU6-904P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 557 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:72,836,745–73,142,318, 1 gene, copy number 6 (within-gene range 3–6): FCHSD2.
- chr11:72,940,498–102,836,766, 556 genes, copy number 6–30 (within-gene range 1–30) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,467. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
